Somatic mutation profile of tumor specimen TCGA-A2-A0YM-01A (aliquot TCGA-A2-A0YM-01A-11D-A10G-09) from TCGA case TCGA-A2-A0YM, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 68.0 years (24,831 days).
Specimen TCGA-A2-A0YM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c80172f6-4568-4a5f-ae5c-70528b5d7ca6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0YM-10A (Blood Derived Normal), aliquot TCGA-A2-A0YM-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12e731de-569d-473e-b699-71f7402855c7

The open-access MAF lists 82 somatic variants for this specimen: 59 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 20, Nonsense Mutation 6, Frame Shift Del 2, Intron 2, 3'Flank 1, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLDC | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 14/181 reads (8%) | catalogued as rs386833585, CM061051, COSV100394072; ClinVar: likely pathogenic; called by muse, mutect2
- ABCA8 | c.3715G>A p.V1239I | Missense Mutation (SNP) | VAF 9/183 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.391); catalogued as COSV99285660; called by muse, mutect2
- ABCF3 | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV53047126; called by muse, mutect2, varscan2
- AKAP9 | c.10799C>A p.S3600Y (on ENST00000359028; = p.S3576Y on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.315); catalogued as COSV62352263; called by muse, mutect2, varscan2
- ARMC4 | c.2360G>A p.R787H | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs376908802; called by muse, mutect2, varscan2
- ATAD5 | c.3560C>G p.S1187* | Nonsense Mutation (SNP) | VAF 40/158 reads (25%) | catalogued as COSV58976683; called by muse, mutect2, varscan2
- C8orf74 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58755938; called by muse, mutect2
- CACNA1F | c.5026G>A p.G1676R | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs782364419, COSV59905701; called by muse, mutect2, varscan2
- CD79B | c.176T>C p.F59S | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV50079324; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1488C>A p.F496L | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs151280101, COSV62572773; called by muse, mutect2, varscan2
- CFAP57 | c.1580T>C p.L527P | Missense Mutation (SNP) | VAF 276/387 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65264974; called by muse, mutect2, varscan2
- CGA | c.30C>G p.I10M | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.061); catalogued as COSV63644796; called by muse, mutect2
- CHD3 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV57877772; called by muse, mutect2, varscan2
- CLEC1B | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754369087, COSV100046061, COSV53725976; called by muse, mutect2
- COL6A3 | c.8639C>T p.T2880M | Missense Mutation (SNP) | VAF 66/271 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs770436761, COSV55098775; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTNNA2 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.079); catalogued as rs778479901, COSV58165297; called by muse, mutect2, varscan2
- DKK2 | c.193G>A p.G65S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1172140233, COSV53397427; called by muse, mutect2, varscan2
- DMRTA1 | c.1357T>C p.S453P | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV57924797; called by muse, mutect2, varscan2
- DNAH2 | c.9353G>A p.R3118Q | Missense Mutation (SNP) | VAF 53/87 reads (61%) | SIFT tolerated (0.15); PolyPhen benign (0.34); catalogued as rs889663031, COSV66722664; called by muse, mutect2, varscan2
- DYTN | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs781120785, COSV71752572; called by muse, mutect2, varscan2
- FLG | c.8713G>C p.E2905Q | Missense Mutation (SNP) | VAF 110/542 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV64243100, COSV64244907; called by muse, mutect2, varscan2
- GBP7 | c.456C>G p.I152M | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1391095615, COSV54009573, COSV99643097; called by muse, mutect2, varscan2
- GET1-SH3BGR | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 49/329 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV61323587; called by muse, mutect2, varscan2
- GLT8D1 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs749077355, COSV56477974; called by muse, mutect2, varscan2
- GNL3 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1393731399, COSV56477965; called by muse, mutect2, varscan2
- H4C13 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV60694665; called by muse, mutect2, varscan2
- HECTD1 | c.140C>G p.T47R | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as COSV67947145, COSV67947915; called by muse, mutect2, varscan2
- HIVEP3 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 81/357 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs751390922, COSV56018437; called by muse, mutect2, varscan2
- JPT1 | c.397G>T p.V133L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.986); catalogued as COSV55470643; called by muse, mutect2, varscan2
- KCND2 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.237); catalogued as COSV58575563; called by muse, mutect2, varscan2
- LYL1 | c.272C>G p.S91C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV99317086; called by muse, mutect2
- MMP26 | c.581C>A p.S194* | Nonsense Mutation (SNP) | VAF 5/61 reads (8%) | catalogued as COSV100332088; called by muse, mutect2
- NLRC4 | c.598G>T p.V200F | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61593845; called by muse, mutect2, varscan2
- NMT2 | c.1443C>A p.Y481* | Nonsense Mutation (SNP) | VAF 40/132 reads (30%) | catalogued as COSV65382686; called by muse, mutect2, varscan2
- NUP62 | c.1564G>C p.D522H | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV61312897; called by muse, varscan2
- OGFOD2 | c.278G>C p.R93P (on ENST00000228922 / NM_001304833.1; = p.R33P on NM_024623.3) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as rs747570505, COSV57441577, COSV99965691; called by muse, mutect2, varscan2
- OR6K2 | c.616G>T p.V206L | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.044); catalogued as COSV62743874; called by muse, mutect2, varscan2
- PEX6 | c.2095-1G>A p.X699_splice | Splice Site (SNP) | VAF 9/55 reads (16%) | catalogued as COSV55104248; called by muse, mutect2, varscan2
- PLCL2 | c.727G>C p.V243L (on ENST00000615277 / NM_001144382.2; = p.V117L on NM_015184.5) | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV67623761; called by muse, mutect2, varscan2
- PRKG2 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 40/131 reads (31%) | catalogued as COSV52328136; called by muse, mutect2, varscan2
- PSTPIP1 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs754304151, COSV51200569; called by muse, mutect2, varscan2
- SCN11A | c.3163C>A p.H1055N | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as COSV56574073; called by muse, mutect2, varscan2
- SRBD1 | c.1726del p.R576Efs*6 | Frame Shift Del (DEL) | VAF 26/149 reads (17%) | catalogued as COSV55397327; called by pindel, varscan2
- SVIL | c.2551C>T p.Q851* (on ENST00000355867 / NM_021738.3; = p.Q425* on NM_003174.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 95/235 reads (40%) | catalogued as COSV63445670; called by muse, mutect2, varscan2
- SYDE2 | c.3531G>C p.L1177F | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100415916; called by muse, mutect2
- SYNGAP1 | c.2561G>A p.R854H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV53383874; called by muse, mutect2, varscan2
- TAOK1 | c.1103T>G p.V368G | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV55595291; called by muse, mutect2, varscan2
- TEX55 | c.1429G>T p.G477C | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.442); catalogued as rs901115647, COSV55212109; called by muse, mutect2, varscan2
- TMEM204 | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs369025963; called by muse, mutect2, varscan2
- TP53 | c.997del p.R333Vfs*12 | Frame Shift Del (DEL) | VAF 19/39 reads (49%) | catalogued as CM137619, COSV52774724; called by mutect2, pindel, varscan2
- TRA2B | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.134); catalogued as COSV52025927; called by muse, mutect2, varscan2
- TUBA3D | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 47/256 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as rs771034023, COSV58312601; called by muse, mutect2, varscan2
- UNC13A | c.2221C>T p.R741C | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53202423; called by muse, mutect2, varscan2
- VPS8 | c.1643G>A p.R548Q (on ENST00000625842 / NM_001349294.1; = p.R546Q on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.036); catalogued as rs752593630, COSV54980422; called by muse, mutect2
- WDR46 | c.1295C>T p.A432V | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.036); catalogued as COSV65851927; called by muse, mutect2, varscan2
- WNK1 | c.2278T>C p.S760P (on ENST00000315939 / NM_018979.4; = p.S759P on NM_014823.3) | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100267268; called by muse, mutect2
- ZNF426 | c.1291T>C p.Y431H | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.992); catalogued as COSV99465165; called by muse, mutect2, varscan2
- ZNF687 | c.2606A>G p.Q869R | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55019646; called by muse, mutect2, varscan2
- TASP1 | c.123_125dup p.G42dup | In Frame Ins (INS) | VAF 28/136 reads (21%) | called by mutect2, varscan2
- ALG10B | c.192A>C p.T64= | Silent (SNP) | VAF 42/346 reads (12%) | catalogued as COSV58143968; called by muse, mutect2, varscan2
- AP1S1 | c.360G>T p.G120= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV50801818; called by muse, mutect2, varscan2
- AP3B1 | c.39A>T p.G13= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV54888130; called by muse, mutect2, varscan2
- ATP6V1C1 | c.354G>A p.L118= | Silent (SNP) | VAF 12/262 reads (5%) | catalogued as COSV101214976; called by muse, mutect2
- CLDN9 | c.489C>G p.S163= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV60910765, COSV60911229; called by muse, varscan2
- DENND2D | c.201A>G p.S67= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV62959597; called by muse, mutect2, varscan2
- DNA2 | c.2037C>T p.H679= | Silent (SNP) | VAF 17/129 reads (13%) | catalogued as rs1307592884, COSV64429287; called by muse, mutect2, varscan2
- ECPAS | c.2892C>T p.V964= | Silent (SNP) | VAF 45/105 reads (43%) | catalogued as COSV52194147, COSV52202620; called by muse, mutect2, varscan2
- GASK1B | c.1559G>A p.*520= | Silent (SNP) | VAF 10/204 reads (5%) | catalogued as COSV56708486; called by muse, mutect2
- GRAMD1B | c.1125G>A p.Q375= | Silent (SNP) | VAF 27/42 reads (64%) | catalogued as rs1304266955, COSV59207950; called by muse, mutect2, varscan2
- KIF1B | c.1707A>T p.I569= (on ENST00000377086 / NM_001365952.1; = p.I523= on NM_015074.3) | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV55812076; called by muse, mutect2, varscan2
- MYH15 | c.342C>G p.L114= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as COSV56315016, COSV99842575; called by muse, mutect2, varscan2
- OR5T3 | c.231T>C p.V77= | Silent (SNP) | VAF 44/190 reads (23%) | catalogued as COSV57381741; called by muse, mutect2, varscan2
- PCDHA12 | c.1671C>T p.D557= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV56495782; called by muse, mutect2, varscan2
- RHPN2 | c.1014C>T p.P338= | Silent (SNP) | VAF 14/125 reads (11%) | catalogued as rs747010837, COSV99577528; called by muse, mutect2, varscan2
- SDAD1 | c.843G>C p.V281= | Silent (SNP) | VAF 46/141 reads (33%) | catalogued as COSV62403338; called by muse, mutect2, varscan2
- SDHD | c.159G>A p.P53= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as rs201368675, COSV54779123; ClinVar: likely benign; called by muse, mutect2, varscan2
- SHMT1 | c.1206G>C p.R402= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV57399750; called by muse, mutect2, varscan2
- STRIP2 | c.2410C>T p.L804= | Silent (SNP) | VAF 19/210 reads (9%) | catalogued as COSV99973779; called by muse, mutect2
- TYR | c.546T>C p.Y182= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV54480798; called by muse, mutect2, varscan2
- CCDC83 | c.794+1281C>T | Intron (SNP) | VAF 51/216 reads (24%) | catalogued as COSV54703654; called by muse, mutect2, varscan2
- ELP5 | c.735+20C>G | Intron (SNP) | VAF 50/100 reads (50%) | catalogued as COSV63039764; called by muse, mutect2, varscan2
- SLCO2A1 | chr3:133928607 G>C | 3'Flank (SNP) | VAF 9/65 reads (14%) | catalogued as COSV60487496; called by muse, mutect2
